Surgical pathology report (de-identified scan), TCGA case TCGA-EL-A4K0, project TCGA-THCA (Thyroid Carcinoma), tissue source site MD Anderson, specimen TCGA-EL-A4K0-01A (Primary Tumor).

DOB: _____ Sex: F
Physician: _____
Accession _____

Collected: _____
Received: _____ Case type: Surgical Case

DIAGNOSIS

(A) TOTAL THYROIDECTOMY:
PAPILLARY THYROID CARCINOMA, CONVENTIONAL TYPE

Location: Right lobe
Multi-focal: No
Size = 1.1 cm
Extrathyroidal extension: Absent
Lymphovascular invasion: Absent
Resection Margins: Negative
Background Thyroid: Multinodular adenomatous goiter
Lymph nodes:
No tumor present in 1 lymph node

ICD-0-3
carcinoma, papillary, thyroid 8260/3
Site: thyroid, nos C73.9
lw
10/4/12

GROSS DESCRIPTION

(A) TOTAL THYROIDECTOMY – Consists of thyroid including right lobe (3.5 x 2.5 x 1.5 cm); left lobe (4.0 x 3.0 x 2.0 cm) and isthmus (1.3 x 1.0 x 0.7 cm). The outer surface is tan-brown, smooth. Sectioning reveals a well-circumscribed tan yellow nodule (1.1 x 1.0 x 1.0 cm), located in the right lobe, another additional two nodules, 0.7 cm and 0.4 cm on the right lobe identified. A tan brown nodule in the left lobe, 0.9 cm in greatest dimension identified.

SECTION CODE: A1, A2, right lobe, largest nodule; A3, A4, two additional nodules, right lobe; A5, A6, left lobe nodule; A7, A8, left lobe representative; A9, isthmus.

CLINICAL HISTORY

Papillary thyroid cancer.

SNOMED CODES

T-B6000, M-A0503, M-Y3420, T-C4200, M-00110, "Some tests reported here may have been developed and performance characteristics determined by these tests have not been specifically cleared or approved by the U.S. Food and Drug Administration."

Entire report and diagnosis completed by:

Surgical Pathology Report

File under: Pathology

Qualifying Institution	DATE	DATE

lw
10/4/12

Source: NCI Genomic Data Commons file 2e477f31-4f80-4ee9-9c48-d447269be81d (TCGA-EL-A4K0.2F14B1E2-580C-4637-9574-DCA2DB4F38C7.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).